Surgical pathology report (de-identified scan), TCGA case TCGA-B8-4621, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-4621-01A (Primary Tumor).

[page 1 of 2]
Diagnosis:

∴ Kidney, left renal tumor #1, partial nephrectomy

Histologic tumor type/subtype: Renal cell carcinoma, clear cell (conventional) type (see comment)

Histologic grade (if applicable): Fuhrman nuclear grade 3 (of 4)

Tumor size (greatest dimension): 5.2 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: negative for tumor

Gerota's fascia: negative for tumor

Renal vein: N/A

Ureter: N/A

Venous (large vessel) not identified

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Perirenal adipose tissue: negative for tumor

Gerota's fascia: negative for tumor

Renal parenchymal margin: negative for tumor

Renal vein: N/A

Renal artery: N/A

Ureter: N/A

Adrenal gland: not submitted

Lymph nodes: no lymph nodes submitted

Other significant findings:

- Nonneoplastic kidney with moderate arteriosclerosis
- Benign simple renal cyst

AJCC Staging:

T1b pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Kidney, left renal tumor #2, biopsy

- Benign cortical cyst, 1.5 cm (see comment)
- No evidence of malignancy

C: Kidney, left renal cyst wall #3, biopsy

- Fragments of benign simple renal cyst
- No evidence of malignancy

Comment:

Sections of specimen B "left renal tumor #2" show a 1.5 cm cyst lined by cytological benign appearing cells ranging in appearance from flattened to cuboidal. There are no solid areas or worrisome features to suggest malignancy. [REDACTED] has reviewed this specimen and agrees with the diagnosis.

Clinical History:

a renal mass.

Gross Description:

Specimen A is additionally labeled "left renal tumor #1, partial nephrectomy" and is a 134.6 gram, 7.5 x 7.5 x 6.5 cm partial nephrectomy covered with a small amount of fat. The exposed parenchymal margin is marked with black ink and the capsule and perinephric soft tissue is marked with blue ink. The specimen is sectioned to demonstrate a well-circumscribed 5.2 cm in diameter spherical yellow/brown solid nodule with focal softening and hemorrhage. The mass expands the renal capsule but does not appear to extend into the perinephric fat. The tumor is well-demarcated from the adjacent renal parenchyma which is remarkable for a 1 cm in diameter thin-walled clear fluid filled cyst (A4). The tumor comes within 0.3 cm of the closest black inked parenchymal margin and abuts the blue inked perinephric soft tissue in multiple areas but does not appear to go through.

Block Summary:

- 1 - Tumor expanding renal capsule
- 2 - Tumor and normal
- A3 - Tumor and closest approach to black inked parenchymal margin
- A4 - Tumor and adjacent cyst
- A5 - Tumor and blue inked perinephric soft tissue
- A6 - Central tumor

[page 2 of 2]
Specimen B is received in a formalin-filled container labeled "left renal tumor #2" and is a 2.7 x 1.8 x 1.0 cm fragment of tissue composed of fat and a 2.4 x 1.0 x 0.6 cm fragment of gray/tan renal tissue. Embedded within the renal tissue is an exposed 1.5 cm in diameter thin-walled membranous area, which may represent cyst wall. It is lined by smooth glistening surfaces. The specimen is sectioned and entirely submitted in blocks B1 and B2.

Specimen C is received in a formalin-filled container labeled "left renal cyst wall #3" and is a 1.6 x 1.1 x 0.6 cm glistening yellow/white membranous tissue fragment, sectioned and entirely submitted in block C1.

Source: NCI Genomic Data Commons file 3d4b07ca-8daf-4fcd-85f0-9657a6f7a133 (TCGA-B8-4621.0713C86B-DFAC-4608-8DAD-6007047856E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).